Surgical pathology report (de-identified scan), TCGA case TCGA-85-8287, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8287-01A (Primary Tumor).

[page 1 of 6]
--	--

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Pulmonectomy Tumor site: Lung Tumor size: 3 x 2.5 x 2.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/3 positive for metastasis (Regional 0/3) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left- upper

[page 4 of 6]
Laterality

Left- upper

[page 5 of 6]
Excision date				Case ID

Source: NCI Genomic Data Commons file a6c6a516-d120-4e7b-8d4f-427cb18969ad (TCGA-85-8287.D57A750C-F51F-474E-8F4A-D2F01926A477.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).